Somatic mutation profile of tumor specimen TCGA-J4-A83N-01A (aliquot TCGA-J4-A83N-01A-11D-A34U-08) from TCGA case TCGA-J4-A83N, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,841 days).
Specimen TCGA-J4-A83N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8df738c-b7b1-4f9b-9fb0-650ff8f2c4df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A83N-10A (Blood Derived Normal), aliquot TCGA-J4-A83N-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5498bf98-29f1-43d0-8b61-c831e2f9483e

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6orf118 | c.515G>T p.R172L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs545305011, COSV100025344, COSV57814424; called by muse, mutect2, varscan2
- CTNNA1 | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV100243370; called by muse, mutect2
- GPCPD1 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV66831024; called by muse, mutect2
- HCK | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99394772; called by muse, mutect2, varscan2
- KIF1A | c.4813G>A p.V1605M (on ENST00000320389 / NM_001379639.1; = p.V1597M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs769279843, COSV57487141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NYAP2 | c.358T>C p.S120P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99796341; called by muse, mutect2
- POP1 | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); catalogued as rs1308548374; called by muse, mutect2
- RBM46 | c.571T>G p.Y191D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99908541; called by muse, mutect2, varscan2
- RBP3 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs1435429358; called by muse, mutect2
- RP1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs747000732, COSV55119519; called by muse, mutect2, varscan2
- SEC31B | c.1771G>T p.D591Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100947314, COSV100947518; called by muse, mutect2, varscan2
- TBC1D32 | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99251676; called by muse, mutect2, varscan2
- CCDC73 | c.592del p.R198Dfs*5 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.56T>A p.M19K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- CNOT3 | c.1932G>A p.P644= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs775049736, COSV99652464; called by muse, mutect2
- CSPP1 | c.3097C>T p.L1033= (on ENST00000676605; = p.L992= on NM_024790.6) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV99140330; called by muse, mutect2, varscan2
- IGHG4 | c.27C>T p.F9= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- LRRC7 | c.1413T>C p.G471= (on ENST00000651989 / NM_001370785.2; = p.G438= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99230707; called by muse, mutect2, varscan2
- MAPKAPK2 | c.355C>A p.R119= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99686284; called by muse, mutect2, varscan2
- PCDHA12 | c.723G>A p.A241= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs1554168359, COSV56543416; called by muse, mutect2
- XDH | c.1116G>A p.L372= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs760097551, COSV101052521; called by muse, mutect2, varscan2
